TARGET case TARGET-30-PADPHP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc129fe7-78ae-5b2c-9517-e6fa605b18ab

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 219 days.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 3.1 years (1,128 days); Year of diagnosis: 1994; Days to last follow up: 219 days; Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: E18.
   Treatment given: Protocol identifier: B003.
   Treatment given: Protocol identifier: 3891.

Follow-up (2 entries)
- Days to follow up: 148 days; Days to first event: 148 days; First event: Event.
- Days to follow up: 219 days; Year of follow up: 1994.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PADPHP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PADPHP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 219
- Protocol: 3891, B003, E18
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Abdominal adrenal left side-no intraspinal ext. Size: 6xm x 4.4xm x 4cm METS: Liver
